Gene-level copy-number profile of tumor specimen SM-JU34B from CPTAC case C204057, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU34B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 84722e81-a971-45f5-81f6-8ae6dae918ff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105284 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/d186dffe-09ca-431d-ac3b-acbce44e4baf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 6,991; copy number 2: 46,317; copy number 3: 4,997; copy number 4: 80.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,991,134–8,848,921, 20 genes (within-gene range 0–1): AL034417.4, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2.
- chr22:45,344,063–45,413,619, 1 gene: SMC1B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,967. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
